Gene-level copy-number profile of tumor specimen TCGA-59-2352-01A from TCGA case TCGA-59-2352, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3.
Specimen TCGA-59-2352-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.a8594369-1e61-444b-a8f9-d47ca065010d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-59-2352-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/96282b5f-5f76-44e8-a593-cc8c618139b8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 3,067; copy number 2: 8,553; copy number 3: 17,208; copy number 4: 21,543; copy number 5: 5,573; copy number 6: 2,508; copy number 7: 735; copy number 8: 106; copy number 9: 65; copy number 10: 252; copy number 11: 73; copy number 12: 27; copy number 17: 77; copy number 22: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-59-2352-01A-01D-0704-01): tumor purity 0.67, ploidy 3.59, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:54,845,189–54,929,189, 1 gene (within-gene range 0–4): CRNDE.
- chr16:54,930,865–55,353,088, 11 genes: IRX5, AC106738.1, AC106738.2, MTND5P34, AC109136.1, AC109462.1, RN7SL841P, AC109462.3, IRX6, AC109462.2, RPL31P56.
- chr16:55,425,574–55,426,130, 1 gene: AC007336.2.
- chr16:59,855,353–60,053,973, 2 genes (within-gene range 0–2): LINC02141, AC009094.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 500 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,703,953–36,775,768, 3 genes, copy number 11: AL596257.1, AC117945.2, AC117945.1.
- chr1:38,474,825–42,164,745, 110 genes, copy number 12–22 (broad region; genes not listed).
- chr12:4,538,798–5,406,651, 27 genes, copy number 9: RAD51AP1, DYRK4, AC005832.2, AC005832.4, AKAP3, AC005832.3, AC005832.1, NDUFA9, AC005833.1, GAU1, GALNT8, AC005833.2, KCNA6, AC006063.1, AC006063.3, AC006063.4, AC005906.2, KCNA1, AC006063.2, AC005906.1, KCNA5, AC005906.3, LINC02443, AC006206.2, AC006206.1, AC007848.2, AC007848.1.
- chr12:24,212,421–34,249,958, 216 genes, copy number 9–10 (broad region; genes not listed).
- chr14:21,918,188–22,499,749, 74 genes, copy number 10 (broad region; genes not listed).
- chr17:1,829,702–3,266,541, 67 genes, copy number 11 (broad region; genes not listed).
- chr17:3,291,017–3,311,934, 3 genes, copy number 11: OR3A1, OR3A4P, AC087498.1.

Autosomal genes at a single copy (total copy number 1): 2,277. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
